Gene-level copy-number profile of tumor specimen C3N-01524-03 from CPTAC case C3N-01524, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.8 years (22,558 days).
Specimen C3N-01524-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bfed1d0d-63b1-48d1-98bf-6d0907fcd38b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01524-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f6b417cf-e79f-4cea-9f2b-2b5f4f75e1e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,125; copy number 2: 53,561; copy number 3: 1,155; copy number 4: 64; copy number 5: 3; copy number 6: 1; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,298,233–21,325,241, 2 genes, copy number 7 (within-gene range 2–7): AC068446.2, RNU6-1235P.
- chr15:21,980,277–21,981,245, 1 gene, copy number 6: OR11J6P.

Autosomal genes at a single copy (total copy number 1): 1,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
